Somatic mutation profile of tumor specimen 0DP7LH from CCDI case PBCDCG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Chordoma, NOS; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 7.1 years (2,591 days).
Specimen 0DP7LH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1378402-7c2e-460e-8fc4-c5f52e85dfa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP7LA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0236049e-dfb1-40fe-a13e-cdd05d6e6a0d

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 7, Nonsense Mutation 3, RNA 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIP | c.162G>A p.A54= | Splice Region (SNP) | VAF 120/674 reads (18%) | catalogued as rs138013399; called by muse, varscan2
- CD69 | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 61/259 reads (24%) | catalogued as COSV57303353; called by muse, varscan2
- FAM50A | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); catalogued as rs1488897646, COSV50132375; called by muse, varscan2
- FCHO2 | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs778153777; called by muse, varscan2
- GLB1L3 | c.1287+5G>A | Splice Region (SNP) | VAF 34/156 reads (22%) | catalogued as rs1178998050; called by muse, varscan2
- HMCN1 | c.15127G>T p.V5043F | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV54873936; called by muse, varscan2
- IFITM3 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60248888, COSV60249414; called by muse, varscan2
- KCNH5 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751953923, COSV59756448; called by muse, varscan2
- KIF2A | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as rs1441214697; called by muse, varscan2
- NOX4 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs147350656; called by muse, varscan2
- PPP1R3A | c.1736C>A p.A579E | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1422000606; called by muse, varscan2
- SATB2 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.114); catalogued as rs1443276216, COSV53479667; called by muse, varscan2
- SDK2 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs139022524; called by muse, varscan2
- SIPA1L1 | c.1838T>C p.V613A | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV62174623; called by muse, varscan2
- SLC16A14 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs368933066; called by muse, varscan2
- SOX8 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as rs1474157051; called by muse, varscan2
- ST8SIA5 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 38/146 reads (26%) | PolyPhen probably damaging (0.989); catalogued as COSV59331350; called by muse, varscan2
- SYNJ1 | c.3809C>T p.S1270L | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1052497631, COSV59144480; ClinVar: uncertain significance; called by muse, varscan2
- ZAN | c.7726G>C p.D2576H | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61818403; called by muse, varscan2
- ADGRV1 | c.5669T>G p.I1890R | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, varscan2
- AFF3 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, varscan2
- BMX | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- EP300 | c.6557A>C p.Q2186P | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- EP300 | c.6558G>C p.Q2186H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, varscan2
- KCND1 | c.1470C>A p.C490* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | called by muse, varscan2
- MEPE | c.1061A>G p.E354G | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, varscan2
- PARP12 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PPP3CA | c.753C>A p.N251K | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TAZ | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- TENM1 | c.4573C>A p.Q1525K | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- TENM1 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.099); called by muse, varscan2
- VARS2 | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, varscan2
- VAV1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- AOAH | c.1095C>T p.I365= | Silent (SNP) | VAF 54/350 reads (15%) | catalogued as rs748997190, COSV51743688; called by muse, varscan2
- ARHGAP39 | c.72G>T p.S24= | Silent (SNP) | VAF 60/423 reads (14%) | called by muse, varscan2
- CHST7 | c.1047C>T p.C349= | Silent (SNP) | VAF 28/154 reads (18%) | called by muse, varscan2
- ETS1 | c.1191C>T p.Y397= | Silent (SNP) | VAF 46/236 reads (19%) | catalogued as rs199698372, COSV60095865; called by muse, varscan2
- FADS3 | c.498C>T p.A166= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs780702718; called by muse, varscan2
- MTMR8 | c.1926C>A p.T642= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, varscan2
- POU5F1 | c.195G>A p.P65= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs747375993; called by muse, varscan2
- TTC22 | c.1317C>A p.G439= | Silent (SNP) | VAF 25/104 reads (24%) | called by muse, varscan2
- USP6NL | c.399A>G p.R133= | Silent (SNP) | VAF 80/324 reads (25%) | called by muse, varscan2
- ATP6AP1L | n.1875G>A | RNA (SNP) | VAF 48/157 reads (31%) | catalogued as rs1011165451; called by muse, varscan2
- CFAP57 | c.3010-409G>T | Intron (SNP) | VAF 92/294 reads (31%) | called by muse, varscan2
- GTSCR1 | n.299A>G | RNA (SNP) | VAF 24/128 reads (19%) | called by muse, varscan2
- IGSF22 | c.2696-219G>T | Intron (SNP) | VAF 33/171 reads (19%) | catalogued as rs1333618583; called by muse, varscan2
- SBNO2 | c.3124-12G>A | Intron (SNP) | VAF 26/110 reads (24%) | called by muse, varscan2
- SLC27A3 | c.2128+32C>T | Intron (SNP) | VAF 14/80 reads (18%) | catalogued as rs374329195; called by muse, varscan2
- SPTLC3 | c.459-53C>T | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as rs755976633; called by muse, varscan2
- STXBP6 | c.452-65G>C | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1428161703; called by muse, varscan2
- TMEM259 | c.1001-22G>A | Intron (SNP) | VAF 22/140 reads (16%) | catalogued as rs1192903372; called by muse, varscan2
- ZNF679 | chr7:64249028 A>G | 5'Flank (SNP) | VAF 10/66 reads (15%) | called by muse, varscan2
